Somatic mutation profile of tumor specimen TCGA-WB-A81I-01A (aliquot TCGA-WB-A81I-01A-11D-A35I-08) from TCGA case TCGA-WB-A81I, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 64.5 years (23,566 days).
Specimen TCGA-WB-A81I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37322c5b-ba45-435d-85e5-c110681a9585.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81I-10A (Blood Derived Normal), aliquot TCGA-WB-A81I-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d6f30f4-bd29-41bb-93a4-9ae6d7362821

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER2 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs745945541, COSV63437872; called by muse, mutect2, varscan2
- MYH3 | c.4501C>G p.R1501G | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551438676, COSV56864534; called by muse, mutect2
- AAK1 | c.1572_1574del p.Q526del | In Frame Del (DEL) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- CNOT1 | c.2810_2811del p.Y937Cfs*3 | Frame Shift Del (DEL) | VAF 44/142 reads (31%) | called by pindel, varscan2
- KIF13B | c.5464A>C p.K1822Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- METTL21C | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRPRA | c.332_338dup p.Q114* | Nonsense Mutation (INS) | VAF 7/28 reads (25%) | called by mutect2, varscan2
- ZNF471 | c.1718G>A p.C573Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF608 | c.3469C>T p.P1157S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- GRK7 | c.1245G>A p.Q415= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- PKHD1L1 | c.5079C>T p.V1693= | Silent (SNP) | VAF 48/107 reads (45%) | catalogued as rs771724295, COSV65748626; called by muse, mutect2, varscan2
